Gene-level copy-number profile of tumor specimen ALCH-ABUA-TTP1-A from ALCHEMIST case ALCH-ABUA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 78.2 years (28,550 days).
Specimen ALCH-ABUA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 31eaa011-5aeb-47b4-a9c8-47ff690d5b4b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ABUA-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,239 have no estimate.
https://portal.gdc.cancer.gov/files/24d5088d-9c35-4bc9-9e5f-f3b049cd0398

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 320; copy number 2: 55,840; copy number 3: 2,182; copy number 4: 14; copy number 5: 10; copy number 6: 1; copy number 7: 6; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–53,312, 7 genes: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P.
- chr1:65,419–71,585, 1 gene: OR4F5.
- chr1:89,551–91,105, 1 gene (within-gene range 0–1): AL627309.3.
- chr2:90,159,840–90,160,335, 1 gene (within-gene range 0–2): IGKV1D-12.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 18 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–64,116, 1 gene, copy number 5: OR4G11P.
- chr11:89,776,981–89,782,582, 1 gene, copy number 8: TRIM64DP.
- chr11:89,797,655–89,808,575, 1 gene, copy number 6: TRIM49.
- chr17:18,390,153–18,400,961, 2 genes, copy number 7: AL353997.5, TBC1D3P4.
- chr17:18,497,095–18,551,705, 4 genes, copy number 7 (within-gene range 3–7): NOS2P2, FAM106A, USP32P2, SRP68P2.
- chr17:19,077,775–19,159,187, 9 genes, copy number 5 (within-gene range 2–5): AC007952.3, KYNUP2, AC007952.7, AC007952.2, AC007952.4, SNORD3D, SNORD3D, GRAPL, AC007952.6.

Autosomal genes at a single copy (total copy number 1): 320. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
